Gene-level copy-number profile of tumor specimen TCGA-CG-5719-01A from TCGA case TCGA-CG-5719, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G1; Age at diagnosis: 54.7 years (19,966 days).
Specimen TCGA-CG-5719-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.7afaa44a-1913-4268-8a8f-743b7fb00d4f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-5719-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d49631e-d33f-4c02-b649-33301b77c501

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 11,488; copy number 2: 37,793; copy number 3: 8,451; copy number 4: 1,903; copy number 5: 138.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-5719-01A-11D-1599-01): tumor purity 0.43, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,219,360–7,441,554, 4 genes: RNU1-8P, CAMTA1-IT1, CAMTA1-AS2, CAMTA1-AS1.
- chr2:235,147,016–236,131,800, 8 genes (within-gene range 0–1): CEP19P1, AC114814.2, AGAP1, AGAP1-IT1, AC064874.1, TMSB10P1, RNU7-127P, RN7SL204P.
- chr6:168,920,394–169,810,102, 27 genes: AL513210.1, AL109924.4, AL109924.3, AL109924.1, AL109924.2, AL136129.1, LINC01615, LINC02544, BX322234.1, THBS2, BX322234.2, VTA1P1, LINC02519, AL009176.1, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 130 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:80,344,853–84,654,343, 130 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,075. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
